Somatic mutation profile of tumor specimen 0DUHHW from CCDI case PBCKRG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 6.1 years (2,245 days).
Specimen 0DUHHW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be354156-854a-47ef-8c6b-f7c250ffd341.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUHG7 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd86dcec-1cf6-4af1-ae9d-7766358c3226

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, 5'UTR 1, Nonsense Mutation 1, Intron 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 435/1073 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 624/1117 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 246/902 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs749953963; called by muse, mutect2, varscan2
- NECTIN4 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 65/601 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs868422471, COSV100919777; called by muse, mutect2, varscan2
- PCDHGA6 | c.992C>T p.A331V | Missense Mutation (SNP) | VAF 341/1179 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.379); catalogued as rs772132262, COSV53896980; called by muse, mutect2, varscan2
- PDCD11 | c.4612G>A p.A1538T | Missense Mutation (SNP) | VAF 123/923 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs988670015, COSV99588590; called by muse, mutect2, varscan2
- PDGFRA | c.863A>G p.Y288C | Missense Mutation (SNP) | VAF 1340/3732 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57264810; called by mutect2, varscan2
- RTP1 | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 222/475 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs771237440, COSV56618586, COSV56619413; called by muse, mutect2, varscan2
- ZNF548 | c.283G>A p.D95N | Missense Mutation (SNP) | VAF 192/1240 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1480826376; called by muse, mutect2, varscan2
- NCAPH | c.2072C>G p.T691R | Missense Mutation (SNP) | VAF 332/1166 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SULT1C3 | c.444C>A p.Y148* | Nonsense Mutation (SNP) | VAF 360/1214 reads (30%) | called by muse, mutect2, varscan2
- UBA1 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 276/466 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKRD26 | c.825A>G p.K275= | Silent (SNP) | VAF 161/1906 reads (8%) | called by muse, mutect2
- FMO1 | c.-1C>T | 5'UTR (SNP) | VAF 296/1199 reads (25%) | called by muse, mutect2, varscan2
- SNAPC3 | c.477+37T>G | Intron (SNP) | VAF 117/942 reads (12%) | called by muse, mutect2, varscan2
